Gene-level copy-number profile of tumor specimen MP2PRT-PAVLIN-TTR1-A from MP2PRT case MP2PRT-PAVLIN, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 9.3 years (3,411 days).
Specimen MP2PRT-PAVLIN-TTR1-A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 348d4fda-457f-494f-9ec9-6b5e3bc60557.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVLIN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/6d4f48fc-5255-4fe4-88d4-7ad62eef7a38

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 326; copy number 1: 2,956; copy number 2: 30,588; copy number 3: 21,287; copy number 4: 17; copy number 5: 1,204; copy number 6: 2,519.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,723 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–248,937,043, 2,524 genes, copy number 5–6 (broad region; genes not listed).
- chr18:45,034–80,247,514, 1,199 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 426. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
